TCGA case TCGA-HJ-7597 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/83d681f4-6c0e-45cc-a31d-0b1b31c8e073

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 805 days (2.2 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Signet ring cell carcinoma (the primary disease): ICD-O-3 morphology code: 8490/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 71.9 years (26,264 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 805 days (2.2 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 37.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride; Days to treatment start: 296 days; Days to treatment end: 471 days (1.3 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 737 days (2.0 years); Days to treatment end: 756 days (2.1 years); Treatment dose: 3,750 cGy; Number of fractions: 15; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Days to treatment start: 793 days (2.2 years); Days to treatment end: 795 days (2.2 years); Treatment outcome: Progressive Disease.
2. Recurrence of diagnosis 1 (Signet ring cell carcinoma). Age at diagnosis: 72.5 years (26,495 days); Days to diagnosis: 231 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site.
3. Metastasis of diagnosis 1 (Signet ring cell carcinoma), site: Brain, NOS. Age at diagnosis: 74.1 years (27,059 days); Days to diagnosis: 795 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 231 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 231 days; Evidence of recurrence type: Convincing Image Source.
- Day 795 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 795 days (2.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 805 days (2.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus / GERD; Reflux treatment type: Proton Pump Inhibitors; Risk factors: Barrett's Esophagus / GERD.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HJ-7597-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-HJ-7597-01A-01-BS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 62; Percent normal cells: 30; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 20.
- Sample TCGA-HJ-7597-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HJ-7597-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach Adenocarcinoma, Signet Ring Type; Cause of death: Stomach Cancer; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: New York; Cancer procurement city: Buffalo; History reflux disease indicator: Yes; Antireflux treatment: Yes; History barretts esophageal indicator: Yes; History hpylori infection indicator: No; Number of relatives with stomach cancer: 0; Treatment outcome first course: Complete Remission/Response.
- Antireflux treatment types: History reflux disease treatment: Antacids.
- Drug treatment 2: Pharmaceutical therapy drug name: camptosar.
- Drug treatment 3: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site other: brain; Treatment outcome at TCGA followup: Partial Remission/Response; Cause of death: Stomach Cancer.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 805 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 805 days; disease-free interval: event (new tumor event after initially disease-free), 231 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 231 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HJ-7597-01A-21D-2200-01): tumor purity 0.42, ploidy 3.69, whole-genome doublings 1.
